Somatic mutation profile of tumor specimen TCGA-OR-A5JR-01A (aliquot TCGA-OR-A5JR-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JR, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 45.5 years (16,604 days).
Specimen TCGA-OR-A5JR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4c160f3b-f75a-4042-a1f8-07c2c6fbc758.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JR-10A (Blood Derived Normal), aliquot TCGA-OR-A5JR-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8cfc0509-d692-482c-8308-e6aa29f570ba

The open-access MAF lists 5 somatic variants for this specimen: 3 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 3, Silent 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CILP2 | c.2944G>A p.E982K | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.74); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- EIF2D | c.104C>G p.T35S | Missense Mutation (SNP) | VAF 89/123 reads (72%) | SIFT tolerated (0.43); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- STXBP4 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.014); called by muse, mutect2
- KANSL2 | c.111C>T p.H37= | Silent (SNP) | VAF 117/247 reads (47%) | called by muse, mutect2, varscan2
- TOGARAM1 | c.5115A>G p.K1705= | Silent (SNP) | VAF 28/72 reads (39%) | called by muse, mutect2, varscan2
